Somatic mutation profile of tumor specimen HCM-BROD-0007-C49-06A (aliquot HCM-BROD-0007-C49-06A-11D-A78T-36) from HCMI case HCM-BROD-0007-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed type rhabdomyosarcoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 12.0 years (4,386 days).
Specimen HCM-BROD-0007-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32a7ff28-034c-424f-a892-8f38c01e5907.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0007-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0007-C49-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49871f99-ba21-4429-a710-9cafc6fcdf7f

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 3, RNA 2, Intron 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 323/724 reads (45%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 132/153 reads (86%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHEK2 | c.1591-2A>T p.X531_splice (on ENST00000382580 / NM_001005735.2; = p.X488_splice on NM_007194.4) | Splice Site (SNP) | VAF 139/386 reads (36%) | catalogued as CS1411626; called by muse, mutect2, varscan2
- GALNTL6 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1233125819; called by muse, mutect2, varscan2
- OBSCN | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs759174505; called by muse, mutect2, varscan2
- RSPH9 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 177/385 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1374850162; called by muse, mutect2, varscan2
- SLC4A5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376704690; called by muse, mutect2, varscan2
- SOAT2 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 152/411 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs150397865; called by muse, mutect2
- ZMYM1 | c.3336G>T p.M1112I | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV63251611; called by muse, mutect2, varscan2
- CASP12 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC152 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- GML | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HERC4 | c.2632G>T p.E878* (on ENST00000395198 / NM_022079.3; = p.E870* on NM_015601.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- MROH2A | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- MRPL48 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NXNL2 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE7A | c.1287del p.R430Gfs*17 (on ENST00000401827 / NM_001242318.3; = p.R404Gfs*17 on NM_002603.4) | Frame Shift Del (DEL) | VAF 54/261 reads (21%) | called by pindel, varscan2
- PRAG1 | c.3391A>T p.N1131Y | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SLC22A14 | c.1729A>T p.I577L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM64C | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 129/215 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZMYM2 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF99 | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CDK7 | c.456A>G p.K152= | Silent (SNP) | VAF 92/216 reads (43%) | called by muse, mutect2, varscan2
- MAGI2 | c.589T>C p.L197= | Silent (SNP) | VAF 169/339 reads (50%) | called by muse, mutect2, varscan2
- NEXN | c.912G>C p.G304= | Silent (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- PMEL | c.846G>A p.E282= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- TADA2B | c.1053G>A p.L351= | Silent (SNP) | VAF 92/195 reads (47%) | called by muse, mutect2, varscan2
- AL021368.4 | n.204A>G | RNA (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- DPCD | c.405-3635C>T | Intron (SNP) | VAF 70/249 reads (28%) | called by muse, mutect2, varscan2
- FLJ40288 | n.1055G>C | RNA (SNP) | VAF 20/38 reads (53%) | called by mutect2, varscan2
- ZNF746 | c.520+917_520+918dup | Intron (INS) | VAF 93/286 reads (33%) | called by mutect2, pindel, varscan2
